Somatic mutation profile of tumor specimen MP2PRT-PAVZFV-TMP1-A (aliquot MP2PRT-PAVZFV-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVZFV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,582 days).
Specimen MP2PRT-PAVZFV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2813c26-320c-4ca4-95d4-833de3931a94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVZFV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVZFV-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/993c3575-1b29-4c92-9fdf-133b77e7d895

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 18, Silent 8, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.7271C>T p.S2424L (on ENST00000272895 / NM_173076.3; = p.S2106L on NM_015657.3) | Missense Mutation (SNP) | VAF 84/238 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs925844991; called by muse, varscan2
- CASP1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 119/177 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV62056518; called by muse, mutect2, varscan2
- CYP4V2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 98/178 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0.32); catalogued as rs779534809, COSV66507800; called by muse, mutect2, varscan2
- DRD2 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 88/104 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs200352240, COSV100669241; called by muse, mutect2, varscan2
- EPHA5 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 48/335 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56634038, COSV56645980, COSV56649011; called by muse, mutect2, varscan2
- FGF14 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 142/349 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs757879324, COSV65935613; called by muse, mutect2, varscan2
- KRTAP10-10 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs782380523; called by muse, mutect2, varscan2
- LIPG | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 160/400 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs758552549, COSV54298012; called by muse, mutect2, varscan2
- LIPM | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV68607195; called by muse, mutect2, varscan2
- PXDNL | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 205/492 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV62478535; called by muse, mutect2, varscan2
- BEX2 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 220/472 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C19orf81 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 57/332 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- CCDC134 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 116/297 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CROCC2 | c.2235G>C p.Q745H | Missense Mutation (SNP) | VAF 191/426 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- KIF1A | c.4870C>T p.R1624W (on ENST00000320389 / NM_001379639.1; = p.R1616W on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 188/396 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MYH14 | c.1089C>T p.I363= | Splice Region (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- NCOR1 | c.4489_4511del p.P1497Cfs*6 | Frame Shift Del (DEL) | VAF 45/87 reads (52%) | called by pindel, varscan2*
- OR5D16 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 174/334 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SPTBN4 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 348/725 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFP37 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARF5 | c.249G>A p.Q83= | Silent (SNP) | VAF 132/289 reads (46%) | catalogued as COSV50002225; called by muse, mutect2, varscan2
- COL14A1 | c.1623G>C p.L541= | Silent (SNP) | VAF 88/246 reads (36%) | catalogued as rs759936513; called by muse, mutect2, varscan2
- DGKD | c.2688C>T p.I896= (on ENST00000264057 / NM_152879.3; = p.I852= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/266 reads (41%) | catalogued as rs1480812455, COSV51040736, COSV99897644; called by muse, mutect2, varscan2
- IGLV4-69 | c.359delinsGGCCCTCC p.*120delinsRPS | Silent (INS) | VAF 30/119 reads (25%) | called by pindel, varscan2*
- MYO16 | c.3828G>T p.S1276= | Silent (SNP) | VAF 276/603 reads (46%) | catalogued as rs761327520; called by muse, mutect2, varscan2
- PCDHB4 | c.255G>C p.L85= | Silent (SNP) | VAF 144/387 reads (37%) | called by muse, mutect2, varscan2
- PTCH1 | c.3705C>T p.S1235= | Silent (SNP) | VAF 265/601 reads (44%) | catalogued as rs1051927200, COSV59490477; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SYT17 | c.30C>T p.N10= | Silent (SNP) | VAF 91/291 reads (31%) | catalogued as rs561317295, COSV100810712; called by muse, mutect2, varscan2
